Gene-level copy-number profile of tumor specimen TCGA-FX-A3TO-01A from TCGA case TCGA-FX-A3TO, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 87.2 years (31,868 days).
Specimen TCGA-FX-A3TO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.90e8e5d6-e4fc-4f69-a746-a2305b5964f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FX-A3TO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5410d513-adcc-41b3-95eb-28bda3dc4ed9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,614; copy number 2: 5,900; copy number 3: 14,345; copy number 4: 12,880; copy number 5: 9,578; copy number 6: 9,192; copy number 7: 2,238; copy number 8: 1,939; copy number 9: 1,220; copy number 10: 364; copy number 11: 512; copy number 12: 2; copy number 13: 2; copy number 17: 1; copy number 18: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FX-A3TO-01A-11D-A227-01): tumor purity 0.77, ploidy 4.16, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,843 genes in 69 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–30,693,984, 454 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr5:32,689,070–45,895,970, 215 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:485,154–4,611,919, 97 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:10,492,223–13,328,583, 52 genes, copy number 7 (within-gene range 5–7): GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2.
- chr7:5,306,790–12,700,889, 131 genes, copy number 9–11 (broad region; genes not listed).
- chr7:36,997,796–38,631,420, 39 genes, copy number 10 (within-gene range 3–10): ELMO1-AS1, RPS17P13, RNU6-565P, RPS10P14, AC078843.1, Y_RNA, NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4, STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH.
- chr7:67,333,047–69,597,493, 23 genes, copy number 7: AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr7:75,769,533–76,177,205, 18 genes, copy number 7: CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3.
- chr7:124,929,873–127,485,804, 24 genes, copy number 7 (within-gene range 6–7): POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1, AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1, MIR592, GRM8-AS1, PRELID3BP10, ZNF800, AC000123.2, AC000123.1, AC000123.3, AC000124.1.
- chr7:143,935,166–148,420,998, 53 genes, copy number 7 (within-gene range 6–7): OR2F2, OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1, OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249.
- chr9:80,357,029–118,083,382, 665 genes, copy number 7–12 (broad region; genes not listed).
- chr11:12,674,421–14,872,044, 40 genes, copy number 8–10 (within-gene range 2–10): TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3.
- chr11:82,689,559–83,423,516, 30 genes, copy number 7: RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:85,336,075–86,423,109, 24 genes, copy number 9: AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81.
- chr11:113,265,137–114,707,069, 41 genes, copy number 7: NCAM1-AS1, AP000880.1, TTC12, AP002840.2, ANKK1, AP002840.1, DRD2, MIR4301, TMPRSS5, MTRF1LP1, ZW10, RPS29P19, AP003170.5, AP003170.4, CLDN25, ATF4P4, AP003170.2, LRRC37A13P, USP28, AP003170.3, AP003170.1, RNU6-1107P, HTR3B, HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2.
- chr11:116,496,899–123,340,714, 209 genes, copy number 7–8 (broad region; genes not listed).
- chr12:4,649,095–5,383,653, 19 genes, copy number 11: NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2.
- chr12:7,304,284–8,830,947, 85 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:9,752,486–10,810,168, 46 genes, copy number 8: CD69, GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2, CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P, MAGOHB, STYK1, YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9.
- chr12:20,695,332–22,618,868, 33 genes, copy number 8 (within-gene range 2–8): SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2.
- chr12:43,633,093–52,573,843, 303 genes, copy number 7–10 (broad region; genes not listed).
- chr12:89,712,048–105,396,097, 297 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr15:19,878,555–28,099,315, 320 genes, copy number 8–11 (broad region; genes not listed).
- chr15:29,674,990–30,355,540, 25 genes, copy number 8 (within-gene range 6–8): AC022613.1, TJP1, AC022613.3, HMGN2P5, AC022613.2, NCAPGP2, AC111152.2, SYNGR2P1, AC111152.1, GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA.
- chr15:33,310,962–47,774,228, 389 genes, copy number 7–18 (within-gene range 4–18) (broad region; genes not listed).
- chr15:49,794,246–51,721,026, 48 genes, copy number 7–11 (within-gene range 4–11): AC025040.2, ATP8B4, AC025040.1, RNA5SP394, SLC27A2, Y_RNA, HDC, RN7SL494P, GABPB1, RNU6-94P, GABPB1-IT1, GABPB1-AS1, AC022087.1, MIR4712, AHCYP7, USP8, RNA5SP395, AC012170.1, USP50, TRPM7, AC084756.1, AC084756.2, RN7SL354P, SPPL2A, AC012100.3, AC012100.2, AC012100.1, AC021752.1, AP4E1, DCAF13P3, MIR4713HG, TNFAIP8L3, AC073964.1, CYP19A1, MIR4713, AC020891.3, MIR7973-2, MIR7973-1, AC020891.2, GLDN, AC020891.4, AC020891.1, AC066613.2, DMXL2, AC066613.1, SCG3, AC020892.1, AC020892.2.
- chr15:57,953,424–61,229,302, 85 genes, copy number 7–11 (within-gene range 1–11) (broad region; genes not listed).
- chr15:61,834,682–64,163,022, 52 genes, copy number 8–10: AC009554.1, VPS13C, AC009554.2, AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1, MIR190A, AC103740.1, AC103740.2, AC079328.1, TPM1, TPM1-AS, AC079328.2, AC087612.1, LACTB, RPS27L, RAB8B, APH1B, CA12, LINC02568, AC007950.1, AC007950.2, USP3, USP3-AS1, FBXL22, HERC1, AC073167.1, MIR422A, AC015914.2, DAPK2, AC015914.1, CIAO2A, SNX1, Y_RNA, SNX22, PPIB.
- chr15:91,408,708–94,070,898, 50 genes, copy number 7 (within-gene range 5–7): CRAT37, AC107958.3, AC107958.2, AC107958.1, THRAP3P2, SLCO3A1, AC116903.2, AC116903.1, DUXAP6, NPM1P5, ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC108457.1, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580.
- chr15:94,841,059–96,327,361, 17 genes, copy number 8 (within-gene range 4–9): AC087633.2, AC107976.1, AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5.
- chr15:96,230,897–101,933,350, 140 genes, copy number 8–9 (broad region; genes not listed).
- chr17:142,789–1,229,738, 34 genes, copy number 8 (within-gene range 6–8): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1.
- chr17:2,962,248–5,448,830, 124 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:6,954,098–7,657,770, 83 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr17:7,717,354–28,196,381, 605 genes, copy number 7–13 (within-gene range 3–13) (broad region; genes not listed).
- chr18:20,946,906–35,143,470, 218 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr18:41,341,319–47,931,146, 86 genes, copy number 7–8 (broad region; genes not listed).
- chr18:54,578,541–80,033,949, 380 genes, copy number 8–9 (broad region; genes not listed).
- chr20:56,577,563–62,573,384, 134 genes, copy number 7–8 (broad region; genes not listed).
- chr22:40,673,484–41,529,273, 34 genes, copy number 7 (within-gene range 1–7): GAPDHP37, MCHR1, SLC25A17, Z98048.1, JTBP1, MIR4766, ST13, XPNPEP3, DNAJB7, Metazoa_SRP, RNU6-379P, RBX1, Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A.

Autosomal genes at a single copy (total copy number 1): 1,205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
